FM case AD2635 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Miscellaneous Tumors.
https://portal.gdc.cancer.gov/cases/94ec848c-750f-41af-b9e7-a71304ccae87

Male, 60.5 years: Chordoma, NOS (ICD-O-3 9370/3); metastasis biopsied or resected from the vertebral column. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Metastatic.
